Somatic mutation profile of tumor specimen C3L-02990-08 (aliquot CPT0238260006) from CPTAC case C3L-02990, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage IB; FIGO stage: Stage IB; Tumor grade: G3; Age at diagnosis: 67.1 years (24,520 days).
Specimen C3L-02990-08: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a3685c9b-78e8-4f7e-a488-f0cd93aeeb50.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02990-31 (Blood Derived Normal), aliquot CPT0238180002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e4f83a63-6d3b-4fdc-8f37-f6677bd3bc93

The open-access MAF lists 75 somatic variants for this specimen: 53 protein-altering or splice-affecting, 13 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 46, Silent 13, Nonsense Mutation 5, Intron 4, 5'UTR 2, 5'Flank 2, Translation Start Site 1, Frame Shift Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBN1 | c.4447G>A p.G1483R | Missense Mutation (SNP) | VAF 182/650 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs794728223, COSV57309338; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PPP2R1A | c.536C>G p.P179R | Missense Mutation (SNP) | VAF 164/289 reads (57%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs786205228, CM153573, COSV59042232, COSV59042841; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTPN11 | c.1530G>C p.Q510H | Missense Mutation (SNP) | VAF 359/635 reads (57%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs397507550, CM117756, COSV61005626, COSV61006865; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.401T>G p.F134C | Missense Mutation (SNP) | VAF 72/105 reads (69%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780442292, CM083195, COSV52669400, COSV52722353; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCG4 | c.1759C>T p.R587* | Nonsense Mutation (SNP) | VAF 28/336 reads (8%) | catalogued as rs760323610; called by muse, mutect2
- ANKRD44 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 31/400 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.287); catalogued as rs762390824, COSV56550727; called by muse, mutect2
- CACNA1I | c.1853C>T p.A618V | Missense Mutation (SNP) | VAF 32/102 reads (31%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs757008650, COSV60803395; called by muse, mutect2, varscan2
- CFAP74 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 178/272 reads (65%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); catalogued as rs1558065145; called by muse, mutect2, varscan2
- CYLC1 | c.336A>C p.K112N | Missense Mutation (SNP) | VAF 52/215 reads (24%) | SIFT tolerated (0.4); PolyPhen benign (0.027); catalogued as COSV61411189; called by muse, mutect2, varscan2
- DEFB119 | c.191G>A p.S64N | Missense Mutation (SNP) | VAF 77/178 reads (43%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.003); catalogued as rs1351262197; called by muse, mutect2, varscan2
- EEA1 | c.46C>T p.Q16* | Nonsense Mutation (SNP) | VAF 90/178 reads (51%) | catalogued as COSV59290194; called by muse, mutect2, varscan2
- EPS8L1 | c.1979C>T p.T660I (on ENST00000201647 / NM_133180.3; = p.T533I on NM_017729.3) | Missense Mutation (SNP) | VAF 251/418 reads (60%) | SIFT deleterious (0); PolyPhen benign (0.397); catalogued as rs1230482471; called by muse, mutect2, varscan2
- EXTL3 | c.322G>A p.A108T | Missense Mutation (SNP) | VAF 186/303 reads (61%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs199979119; called by muse, mutect2, varscan2
- FCAR | c.205C>G p.R69G | Missense Mutation (SNP) | VAF 110/435 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV62028348, COSV62029418; called by muse, mutect2, varscan2
- GLI3 | c.4250G>A p.R1417K | Missense Mutation (SNP) | VAF 683/1127 reads (61%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.006); catalogued as COSV67887783; called by muse, mutect2, varscan2
- INAFM1 | c.416G>A p.R139Q | Missense Mutation (SNP) | VAF 102/372 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.552); catalogued as rs1418041671; called by muse, mutect2, varscan2
- KIF20A | c.1733G>A p.R578Q | Missense Mutation (SNP) | VAF 40/186 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs374968389; called by muse, mutect2, varscan2
- MAN2B1 | c.1754G>A p.R585H | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.067); catalogued as rs1374305848, COSV99667052; called by muse, mutect2, varscan2
- MAST3 | c.2926G>A p.V976I | Missense Mutation (SNP) | VAF 75/241 reads (31%) | SIFT tolerated (0.46); PolyPhen benign (0.062); catalogued as rs755807326, COSV53222737; called by muse, mutect2, varscan2
- MUC16 | c.20491A>G p.M6831V | Missense Mutation (SNP) | VAF 148/178 reads (83%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs373272807; called by muse, mutect2, varscan2
- NEXN | c.1328T>C p.I443T | Missense Mutation (SNP) | VAF 62/192 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs1305454215; called by muse, mutect2, varscan2
- OSR2 | c.337C>T p.R113W | Missense Mutation (SNP) | VAF 51/143 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV99882786; called by muse, mutect2, varscan2
- PPP6R2 | c.1240G>A p.E414K | Missense Mutation (SNP) | VAF 117/319 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs376757157, COSV53290792; called by muse, mutect2, varscan2
- PRB3 | c.115C>T p.R39* | Nonsense Mutation (SNP) | VAF 27/280 reads (10%) | catalogued as rs533793961, COSV54389356; called by muse, mutect2
- PREPL | c.1027A>G p.M343V | Missense Mutation (SNP) | VAF 92/161 reads (57%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs771442588, COSV53219890; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PSG8 | c.841C>A p.P281T | Missense Mutation (SNP) | VAF 126/524 reads (24%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.707); catalogued as COSV60609742; called by muse, mutect2, varscan2
- RYR1 | c.11497G>A p.A3833T | Missense Mutation (SNP) | VAF 310/552 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.086); catalogued as rs764827061; called by muse, mutect2, varscan2
- SORL1 | c.2722G>T p.D908Y | Missense Mutation (SNP) | VAF 104/397 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52756770; called by muse, mutect2, varscan2
- TENM3 | c.6593G>A p.R2198H | Missense Mutation (SNP) | VAF 79/119 reads (66%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.98); catalogued as rs201676320, COSV69308961, COSV69312882; called by muse, mutect2, varscan2
- TMEM45A | c.125C>A p.S42Y | Missense Mutation (SNP) | VAF 31/145 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as COSV60255891; called by muse, mutect2, varscan2
- COL15A1 | c.1535C>G p.A512G | Missense Mutation (SNP) | VAF 154/303 reads (51%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- DGKZ | c.128G>A p.R43Q | Missense Mutation (SNP) | VAF 49/115 reads (43%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- ECPAS | c.4593G>T p.Q1531H | Missense Mutation (SNP) | VAF 64/225 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- GLYR1 | c.152A>T p.D51V | Missense Mutation (SNP) | VAF 247/264 reads (94%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); called by muse, mutect2, varscan2
- GPR101 | c.935T>C p.V312A | Missense Mutation (SNP) | VAF 65/223 reads (29%) | SIFT tolerated, low confidence (0.95); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- GPR173 | c.74A>G p.K25R | Missense Mutation (SNP) | VAF 30/113 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.452); called by muse, mutect2, varscan2
- GPRIN3 | c.891A>C p.E297D | Missense Mutation (SNP) | VAF 153/290 reads (53%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- GRIP1 | c.1972G>A p.E658K (on ENST00000359742 / NM_001379345.1; = p.E606K on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 73/218 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.757); called by muse, mutect2, varscan2
- HS1BP3 | c.431G>A p.G144E | Missense Mutation (SNP) | VAF 141/221 reads (64%) | SIFT deleterious (0.04); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- LMO7 | c.3724A>T p.R1242W (on ENST00000357063; = p.R923W on NM_005358.5) | Missense Mutation (SNP) | VAF 37/226 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- LRTM2 | c.125C>A p.S42Y | Missense Mutation (SNP) | VAF 56/196 reads (29%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.663); called by muse, mutect2, varscan2
- LSM1 | c.109C>T p.Q37* | Nonsense Mutation (SNP) | VAF 58/254 reads (23%) | called by muse, mutect2, varscan2
- MECOM | c.1810C>T p.R604* (on ENST00000468789 / NM_001105078.4; = p.R792* on NM_004991.4) | Nonsense Mutation (SNP) | VAF 96/724 reads (13%) | called by muse, mutect2, varscan2
- MED13L | c.2743A>G p.M915V | Missense Mutation (SNP) | VAF 168/503 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- POM121L12 | c.131C>T p.P44L | Missense Mutation (SNP) | VAF 67/275 reads (24%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2, varscan2
- PPP2R3B | c.1085G>T p.R362L | Missense Mutation (SNP) | VAF 81/715 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RALGAPA1 | c.1640T>A p.I547K | Missense Mutation (SNP) | VAF 48/91 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.074); called by mutect2, varscan2
- RFK | c.335del p.L112* | Frame Shift Del (DEL) | VAF 33/134 reads (25%) | called by mutect2, pindel, varscan2
- RSBN1 | c.464G>A p.G155E | Missense Mutation (SNP) | VAF 125/153 reads (82%) | SIFT tolerated, low confidence (0.75); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- TRPC4 | c.978G>T p.W326C | Missense Mutation (SNP) | VAF 12/245 reads (5%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.987); called by muse, mutect2
- VPS50 | c.1915A>T p.M639L | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- VSTM2A | c.163G>A p.A55T | Missense Mutation (SNP) | VAF 127/440 reads (29%) | SIFT tolerated (0.86); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ZNF91 | c.161T>G p.I54S | Missense Mutation (SNP) | VAF 88/180 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.376); called by muse, mutect2, varscan2
- ACSL4 | c.891T>C p.A297= (on ENST00000340800 / NM_022977.2; = p.A256= on NM_004458.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 14/360 reads (4%) | called by muse, mutect2
- ADAMTS10 | c.2820C>T p.H940= | Silent (SNP) | VAF 71/79 reads (90%) | called by muse, mutect2, varscan2
- ARIH1 | c.255C>T p.G85= | Silent (SNP) | VAF 7/99 reads (7%) | catalogued as rs754910711, COSV65910196; called by muse, mutect2
- COL2A1 | c.1452C>T p.P484= | Silent (SNP) | VAF 164/907 reads (18%) | catalogued as rs755093756, COSV61527781; ClinVar: likely benign; called by muse, mutect2, varscan2
- CUBN | c.6750C>T p.I2250= | Silent (SNP) | VAF 98/152 reads (64%) | called by muse, mutect2, varscan2
- F2RL3 | c.831C>G p.R277= | Silent (SNP) | VAF 90/426 reads (21%) | called by muse, varscan2
- FAT1 | c.9588C>T p.T3196= | Silent (SNP) | VAF 46/169 reads (27%) | called by muse, mutect2, varscan2
- HS6ST2 | c.273C>G p.S91= | Silent (SNP) | VAF 85/367 reads (23%) | called by muse, mutect2, varscan2
- KIT | c.978C>T p.N326= | Silent (SNP) | VAF 65/97 reads (67%) | catalogued as rs148594615; ClinVar: uncertain significance / conflicting interpretations of pathogenicity / likely benign; called by muse, mutect2, varscan2
- LRSAM1 | c.819C>G p.R273= | Silent (SNP) | VAF 172/566 reads (30%) | called by muse, mutect2, varscan2
- MFHAS1 | c.2061G>A p.A687= | Silent (SNP) | VAF 141/222 reads (64%) | called by muse, mutect2, varscan2
- VPS35 | c.2016C>T p.T672= | Silent (SNP) | VAF 120/262 reads (46%) | catalogued as rs746999621; called by muse, mutect2, varscan2
- ZFP36L2 | c.204G>C p.A68= | Silent (SNP) | VAF 71/211 reads (34%) | called by muse, mutect2, varscan2
- AL353804.7 | chrX:73848402 G>A | 5'Flank (SNP) | VAF 40/235 reads (17%) | called by muse, mutect2, varscan2
- CCDC159 | c.22-22C>G | Intron (SNP) | VAF 63/326 reads (19%) | called by muse, mutect2, varscan2
- CDC45 | chr22:19479536 del A | 5'Flank (DEL) | VAF 45/120 reads (38%) | called by mutect2, pindel, varscan2
- CTBP2 | c.58+12457C>A | Intron (SNP) | VAF 53/191 reads (28%) | called by mutect2, varscan2
- DTNBP1 | c.-99del | 5'UTR (DEL) | VAF 68/287 reads (24%) | called by mutect2, pindel, varscan2
- OR4C4P | n.87C>A | RNA (SNP) | VAF 77/148 reads (52%) | called by muse, mutect2, varscan2
- SCN7A | c.2158-3598G>T | Intron (SNP) | VAF 94/179 reads (53%) | called by muse, mutect2, varscan2
- TRIM5 | c.895+66A>T | Intron (SNP) | VAF 11/39 reads (28%) | catalogued as COSV100000253; called by muse, mutect2, varscan2
- ZBTB14 | c.-34G>A | 5'UTR (SNP) | VAF 16/82 reads (20%) | catalogued as rs201350612; called by muse, mutect2, varscan2
